Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7CK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7CK-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F
DOB: [REDACTED] (Age: [REDACTED])

Service: [REDACTED]
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Physician(s): [REDACTED] M.D.

DIAGNOSIS:

UTERUS, CERVIX, BIOPSY
- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED WITH FOCAL KERATINIZATION

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

Report Electronically Reviewed and Signed Out By [REDACTED] M.D.

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] year old woman with a pelvic mass. Operative procedure: Cervical biopsy.

Specimen(s) Received:

CERVICAL BIOPSY

ICD-O-3

Carcinoma, squamous cell NOS 8070/3

Site: Cervix NOS C53.9

QW 8/27/13

Gross Description

The specimen is received in a single formalin-filled container labeled with the patient's name and "cervical biopsy." It contains clotted blood and multiple fragments of irregular, brown and white tissue measuring 1.3 x 1.1 x 0.5 cm in aggregate. Wrapped in tissue paper. Labeled A1. Jar 0.

[REDACTED] M.D., Ph.D.

This Surgical Pathology report is available on-line on [REDACTED]

Physician Copy [REDACTED]
END OF REPORT

Source: NCI Genomic Data Commons file 415c0378-4069-43e8-83df-9bfeeb3db7a7 (TCGA-C5-A7CK.6E6806E3-7BAD-48EB-AAE9-9C15DAC56B2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).